Somatic mutation profile of tumor specimen TCGA-D7-6817-01A (aliquot TCGA-D7-6817-01A-11D-1882-08) from TCGA case TCGA-D7-6817, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 63.4 years (23,142 days).
Specimen TCGA-D7-6817-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ac7629d3-f48b-4c91-80c4-049113b35a67.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D7-6817-10A (Blood Derived Normal), aliquot TCGA-D7-6817-10A-01D-1882-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ed225cfe-7cb1-47bd-be03-31471abf4023

The open-access MAF lists 83 somatic variants for this specimen: 64 protein-altering or splice-affecting, 17 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 61, Silent 17, Intron 1, Nonsense Mutation 1, In Frame Del 1, 3'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EYA4 | c.455T>G p.L152R | Missense Mutation (SNP) | VAF 22/224 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62044745, COSV62052190, COSV62055739; called by muse, mutect2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 10/33 reads (30%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACTN3 | c.2432A>T p.N811I | Missense Mutation (SNP) | VAF 54/320 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV59749466; called by muse, mutect2, varscan2
- ADGRG7 | c.146C>T p.T49I | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV56298290; called by muse, mutect2, varscan2
- ANKRD52 | c.238C>T p.R80C | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs866200913, COSV57282772; called by muse, mutect2, varscan2
- ARPP21 | c.1482T>A p.D494E | Missense Mutation (SNP) | VAF 16/155 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV51801350; called by muse, mutect2, varscan2
- ASH1L | c.6479G>A p.R2160K (on ENST00000368346 / NM_001366177.2; = p.R2155K on NM_018489.3) | Missense Mutation (SNP) | VAF 27/151 reads (18%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.972); catalogued as COSV100853631, COSV64209943; called by muse, mutect2, varscan2
- ATOH8 | c.107G>C p.R36P | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.989); catalogued as COSV60400935; called by muse, mutect2, varscan2
- ATP7B | c.4232G>A p.R1411Q | Missense Mutation (SNP) | VAF 33/122 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.1); catalogued as rs769672624, COSV54440267; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CANT1 | c.901C>T p.R301C | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1002771742, COSV56605968; called by muse, mutect2
- CARMIL3 | c.3859C>T p.R1287C | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.982); catalogued as rs376849687; called by muse, mutect2, varscan2
- CEP55 | c.820A>G p.K274E | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.292); catalogued as COSV65185372; called by muse, mutect2
- COL14A1 | c.2416G>C p.V806L | Missense Mutation (SNP) | VAF 67/416 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.653); catalogued as COSV52859190; called by muse, mutect2, varscan2
- COPB1 | c.842C>T p.A281V | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as rs780242730, COSV51447174, COSV99999337; called by mutect2, varscan2
- CWH43 | c.500G>A p.R167H | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); catalogued as rs371671107; called by muse, mutect2, varscan2
- DNAH8 | c.8878C>G p.R2960G | Missense Mutation (SNP) | VAF 16/137 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV59459174; called by muse, mutect2, varscan2
- ESR1 | c.1060C>A p.L354M | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52794371; called by muse, mutect2, varscan2
- ESR2 | c.519T>A p.F173L | Missense Mutation (SNP) | VAF 64/352 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50833811; called by muse, mutect2, varscan2
- ESRRB | c.301C>T p.R101C | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1384707734, COSV55060809; called by muse, mutect2, varscan2
- EVI2B | c.1330C>A p.P444T | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV58364412; called by muse, mutect2
- FHL5 | c.55A>C p.K19Q | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.285); catalogued as COSV58738608; called by muse, mutect2, varscan2
- FRY | c.8971C>T p.R2991C | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.03); catalogued as COSV66511422; called by muse, mutect2, varscan2
- FZD10 | c.541C>G p.P181A | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.017); catalogued as COSV57474300; called by muse, mutect2, varscan2
- GPRIN3 | c.1183C>G p.Q395E | Missense Mutation (SNP) | VAF 32/160 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.461); catalogued as rs1024549870, COSV60885406, COSV60885712; called by muse, mutect2, varscan2
- GRIK5 | c.2015G>A p.G672D | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868949498, COSV53480952; called by muse, mutect2, varscan2
- HECW2 | c.107C>G p.S36C | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.338); catalogued as COSV53664411; called by muse, mutect2, varscan2
- HNRNPU | c.823A>G p.I275V (on ENST00000283179; = p.I337V on NM_004501.3) | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as COSV51692193; called by muse, mutect2, varscan2
- HTT | c.4686A>C p.K1562N | Missense Mutation (SNP) | VAF 14/139 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as COSV61857126, COSV61864645; called by muse, mutect2
- KCNIP3 | c.534G>T p.K178N | Missense Mutation (SNP) | VAF 27/173 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV54670343; called by muse, mutect2, varscan2
- KIF2B | c.344G>C p.W115S | Missense Mutation (SNP) | VAF 23/194 reads (12%) | SIFT tolerated (0.87); PolyPhen benign (0.017); catalogued as COSV52132430; called by muse, mutect2, varscan2
- KLHL23 | c.106A>T p.T36S | Missense Mutation (SNP) | VAF 32/144 reads (22%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.673); catalogued as COSV55868199; called by muse, mutect2, varscan2
- LCT | c.424C>T p.R142W | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs760712703, COSV51465173; called by muse, mutect2, varscan2
- LHCGR | c.1426C>G p.Q476E | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.175); catalogued as COSV54299173, COSV54300425; called by muse, mutect2, varscan2
- MAGEB1 | c.622A>G p.I208V | Missense Mutation (SNP) | VAF 14/21 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV66775986; called by muse, mutect2, varscan2
- MBD5 | c.1736T>G p.L579* | Nonsense Mutation (SNP) | VAF 29/198 reads (15%) | catalogued as COSV68698091; called by muse, mutect2, varscan2
- MRC2 | c.339C>G p.D113E | Missense Mutation (SNP) | VAF 11/132 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57641412; called by muse, mutect2
- MTUS2 | c.2983C>T p.R995W | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764265852, COSV70913437; called by muse, mutect2, varscan2
- MUC16 | c.24344C>A p.P8115Q | Missense Mutation (SNP) | VAF 52/152 reads (34%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.295); catalogued as rs777856268, COSV67476246; called by muse, mutect2, varscan2
- MYH8 | c.4247C>T p.S1416F | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.169); catalogued as COSV67959132; called by muse, mutect2, varscan2
- OR9G1 | c.320C>A p.A107D | Missense Mutation (SNP) | VAF 43/311 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV100380294, COSV56451194; called by muse, mutect2
- PAPPA | c.1853G>T p.G618V | Missense Mutation (SNP) | VAF 77/362 reads (21%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.981); catalogued as COSV60279974, COSV60281234; called by muse, mutect2, varscan2
- PGR | c.80T>C p.L27P | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.761); catalogued as COSV54804495; called by muse, mutect2
- PID1 | c.545G>C p.W182S (on ENST00000354069 / NM_001330156.1; = p.W180S on NM_017933.5) | Missense Mutation (SNP) | VAF 22/170 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62477940, COSV62484632; called by muse, mutect2, varscan2
- PPAT | c.1418T>C p.I473T | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.097); catalogued as COSV51705038; called by muse, mutect2, varscan2
- PREX2 | c.193G>T p.V65L | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as COSV99905658; called by muse, mutect2, varscan2
- PREX2 | c.194T>A p.V65E | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.633); catalogued as COSV99905660; called by muse, mutect2, varscan2
- PREX2 | c.1460G>T p.C487F | Missense Mutation (SNP) | VAF 11/199 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV55780673; called by muse, mutect2
- SGIP1 | c.448C>A p.P150T | Missense Mutation (SNP) | VAF 27/195 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52772602; called by muse, mutect2, varscan2
- SHOX | c.59A>G p.N20S | Missense Mutation (SNP) | VAF 45/421 reads (11%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV61861344; called by muse, mutect2, varscan2
- SLC26A7 | c.1072T>G p.F358V | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.451); catalogued as COSV52596947; called by muse, varscan2
- SLCO5A1 | c.1692C>A p.H564Q | Missense Mutation (SNP) | VAF 18/134 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); catalogued as COSV52662070; called by muse, mutect2, varscan2
- SLIT2 | c.3801G>C p.L1267F | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs1256776420, COSV56579015; called by muse, mutect2, varscan2
- STUB1 | c.629A>C p.D210A | Missense Mutation (SNP) | VAF 14/379 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.021); catalogued as COSV50199181; called by muse, mutect2
- TBXA2R | c.289G>A p.A97T | Missense Mutation (SNP) | VAF 48/86 reads (56%) | SIFT tolerated (0.64); PolyPhen benign (0.039); catalogued as COSV64343990; called by muse, mutect2, varscan2
- TCERG1L | c.666C>G p.I222M | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV64052095; called by muse, mutect2
- TLE4 | c.1636C>T p.R546C | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.081); catalogued as rs140356709, COSV54634897; called by muse, mutect2, varscan2
- TTN | c.72763G>A p.G24255R (on ENST00000591111; = p.G16831R on NM_003319.4) | Missense Mutation (SNP) | VAF 13/74 reads (18%) | PolyPhen probably damaging (1); catalogued as COSV60068446; called by muse, mutect2, varscan2
- WIPF1 | c.1058G>A p.R353H | Missense Mutation (SNP) | VAF 36/172 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV55814871; called by muse, mutect2, varscan2
- ZFHX4 | c.3290T>A p.I1097N | Missense Mutation (SNP) | VAF 28/304 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.165); catalogued as COSV50981818, COSV51456374; called by muse, mutect2
- ZKSCAN8 | c.709G>C p.D237H | Missense Mutation (SNP) | VAF 28/151 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.682); catalogued as COSV57639071; called by muse, mutect2, varscan2
- ZNF33B | c.566A>G p.E189G | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as COSV63942822; called by muse, mutect2, varscan2
- ZNF479 | c.1241G>C p.C414S | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.47); catalogued as COSV100482423, COSV100482581; called by mutect2, varscan2
- CDR1 | c.605_642del p.G202Dfs*11 | Frame Shift Del (DEL) | VAF 58/162 reads (36%) | called by muse*, mutect2, pindel, varscan2*
- PIK3R1 | c.1345_1380del p.L449_S460del (on ENST00000521381 / NM_181523.3; = p.L179_S190del on NM_181504.4) | In Frame Del (DEL) | VAF 9/85 reads (11%) | called by mutect2, pindel
- APCDD1L | c.1041C>T p.G347= | Silent (SNP) | VAF 15/81 reads (19%) | catalogued as rs572379948, COSV64486926; called by muse, mutect2, varscan2
- BSN | c.2352C>T p.D784= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as rs147936824, COSV56521562; called by muse, mutect2, varscan2
- DCAF12L2 | c.372C>T p.D124= | Silent (SNP) | VAF 55/81 reads (68%) | catalogued as COSV63582640; called by muse, mutect2, varscan2
- EIF3H | c.408T>C p.S136= | Silent (SNP) | VAF 22/173 reads (13%) | catalogued as COSV52668511; called by muse, mutect2, varscan2
- EPDR1 | c.231G>A p.R77= | Silent (SNP) | VAF 4/46 reads (9%) | catalogued as COSV52260542; called by muse, mutect2
- GP9 | c.114C>T p.C38= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as COSV56624382; called by muse, mutect2, varscan2
- H2BC6 | c.264G>C p.S88= | Silent (SNP) | VAF 53/236 reads (22%) | catalogued as rs779369515, COSV61591350; called by muse, mutect2, varscan2
- LRRK2 | c.3048G>T p.L1016= | Silent (SNP) | VAF 10/71 reads (14%) | catalogued as COSV54158953, COSV54176505; called by muse, mutect2, varscan2
- MAPK8IP1 | c.786G>A p.S262= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as rs760993099, COSV53798676; called by mutect2, varscan2
- MARF1 | c.3822A>G p.Q1274= | Silent (SNP) | VAF 14/93 reads (15%) | catalogued as rs368620760; called by muse, mutect2, varscan2
- NRXN1 | c.4380T>C p.S1460= | Silent (SNP) | VAF 16/98 reads (16%) | catalogued as COSV60506785; called by muse, mutect2, varscan2
- OR14I1 | c.666G>A p.T222= | Silent (SNP) | VAF 80/171 reads (47%) | catalogued as rs112867044, COSV61200159; called by muse, mutect2, varscan2
- PELI2 | c.534C>T p.P178= | Silent (SNP) | VAF 23/143 reads (16%) | catalogued as rs146968853; called by muse, mutect2, varscan2
- RASGRP3 | c.486T>C p.F162= | Silent (SNP) | VAF 40/236 reads (17%) | catalogued as COSV67822993; called by muse, mutect2, varscan2
- RTEL1 | c.3267C>T p.D1089= | Silent (SNP) | VAF 23/256 reads (9%) | catalogued as rs370637234; ClinVar: likely benign; called by muse, mutect2
- SCN1A | c.5007G>A p.A1669= (on ENST00000303395 / NM_001202435.3; = p.A1658= on NM_006920.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 34/187 reads (18%) | catalogued as rs750366817, COSV57675680; ClinVar: likely benign; called by muse, mutect2, varscan2
- TENM4 | c.5292C>T p.A1764= | Silent (SNP) | VAF 16/40 reads (40%) | catalogued as rs765617077, COSV53641956; called by muse, mutect2, varscan2
- ANKRD13D | c.*1304C>T | 3'UTR (SNP) | VAF 11/79 reads (14%) | catalogued as COSV100354437; called by muse, mutect2, varscan2
- GREB1 | c.1160-1305C>T | Intron (SNP) | VAF 10/53 reads (19%) | catalogued as rs778283551, COSV52189778; called by muse, mutect2, varscan2
